Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A7II, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A7II-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Form Revised

Fax:

Clinical Case Report

ICD-13

Carcinoma, hepatocellular
N63 8/70/13

Site Liver C22.0
Q 10/10/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☒ Male ☐ Female			11/6	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Tired of eating; fever; fatigue.
Symptoms: yellow skin; weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1/2 p/day	30 (yrs)	3 months ago (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink/day	20 (yrs)	6 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour was found in the liver	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Liver Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging	Date of Diagnosis	
T3 N0 M0	Stage: IIIA	

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of the right liver		
Primary Tumor		
Organ	Detailed Location	Size
Liver tumor	Right liver	10 x 7 x 6 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N0 M0		Stage: IIIA

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

Date: _____

Time: _____

Preserved by: _____

Date: _____

Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	10 x 7 x 0 cm	RESECT LIVER	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT3	N0	M0	Stage: IIIA
Notes:			

[page 5 of 5]
IRB APPROVED

Form Revised

Tel:

Fax:

Consolidated Pathology Diagnosis

Histological Pattern							
Cell Distribution		+	-	Structural Pattern		+	-
Diffuse			X	Streaming			
Mosaic		X		Storiform			
Necrosis		X		Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		X		Round Cell				Large Cell			
Spindle Cell				Cell Stratification		X		Fibroblast				Small Cell			
Keratin				Secretion		X		Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole		X		Lipoblast				Inflam. Cell			
Pearl				Gland formation		X		Myoblast				Plasma Cell			

Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor

Nuclear Atypia:				
	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism				X
Nucleolar Prominent				X
Multinucleated Giant Cell				X
Mitotic Activity				X

Nuclear Grade: ☒ III

D1 70% D2 70% D3 70% D4 40% Necrosis 10%

Final Pathology Report

Histological Diagnosis: Hepatocellular carcinoma, pseudoglandular type (adenoma) **Grade:** 3

Comments:

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

Date: 8/30/13

Pr or Malignancy History		X

Source: NCI Genomic Data Commons file b5c34538-bd50-4257-8769-c37eced5617f (TCGA-CC-A7II.A5E3C73D-B84B-4D1C-858F-4B4392341610.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).